Somatic mutation profile of tumor specimen TCGA-BR-8058-01A (aliquot TCGA-BR-8058-01A-31D-2340-08) from TCGA case TCGA-BR-8058, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.8 years (19,658 days).
Specimen TCGA-BR-8058-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db965d4d-91bf-4cce-8d1a-d36794c55a6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8058-10A (Blood Derived Normal), aliquot TCGA-BR-8058-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e3228bc-7374-4a11-af3d-6946f5189dc4

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 26/86 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555515445, CM1511046, COSV55727198, COSV55729198, COSV55735587; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.1091A>G p.Y364C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886039177, COSV59281383, COSV59285979; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1A3 | c.1236T>G p.I412M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV60902207; called by muse, mutect2, varscan2
- CDHR2 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1438878369, COSV56135159; called by muse, mutect2, varscan2
- CFAP57 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs375761680; called by muse, mutect2, varscan2
- CLCN5 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV56585144; called by muse, mutect2, varscan2
- DCC | c.1231A>G p.T411A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59114561; called by muse, mutect2, varscan2
- DENND5A | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV60235367; called by muse, mutect2, varscan2
- EEF2 | c.820A>G p.S274G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1334138285, COSV58578420, COSV58579997; called by muse, mutect2
- ELFN2 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68745227; called by muse, mutect2
- FMR1 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV54425453, COSV99503189; called by muse, mutect2, varscan2
- HAPLN3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV61363826; called by muse, mutect2, varscan2
- HDAC10 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV50556353, COSV50561141; called by muse, mutect2, varscan2
- KRTAP9-3 | c.137G>C p.C46S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); catalogued as COSV100893214, COSV100893278; called by muse, mutect2, varscan2
- MAGED1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); catalogued as COSV58515868, COSV58517080; called by muse, mutect2, varscan2
- MIS18BP1 | c.2233A>G p.T745A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60371747; called by muse, mutect2, varscan2
- OR4C15 | c.156G>C p.L52F | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs539675118, COSV58952708, COSV58953821; called by muse, mutect2, varscan2
- ORC3 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57641518; called by muse, mutect2, varscan2
- PDE4D | c.1697T>C p.V566A (on ENST00000340635 / NM_001104631.2; = p.V430A on NM_006203.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.99); catalogued as COSV57718840; called by muse, mutect2
- PENK | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV59242175; called by muse, mutect2, varscan2
- PLXNA4 | c.2710T>G p.L904V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV58139992; called by muse, mutect2
- PRF1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV64615351; called by muse, mutect2
- PSG1 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV99741358, COSV99741709; called by muse, mutect2
- PTGFR | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV66115553, COSV66115721; called by muse, mutect2
- RBM42 | c.1292A>G p.D431G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52898167; called by muse, mutect2
- RGS9 | c.1886T>C p.V629A | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.057); catalogued as COSV52226938; called by muse, mutect2
- RPL11 | c.6+1G>T p.X2_splice | Splice Site (SNP) | VAF 18/91 reads (20%) | catalogued as COSV65778467, COSV65778901, COSV99068788; called by muse, mutect2, varscan2
- SLC13A5 | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53423822; called by muse, mutect2, varscan2
- SLC7A6 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV50450291; called by muse, mutect2, varscan2
- SULF1 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52685908, COSV99482979; called by muse, mutect2, varscan2
- TOPORS | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62117424; called by muse, mutect2, varscan2
- ZNF93 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.55); catalogued as COSV59376633; called by muse, varscan2
- AP4B1 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); called by muse, mutect2
- ACAD11 | c.720G>A p.V240= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV53898453; called by muse, mutect2
- DDX21 | c.57A>G p.K19= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV62556000; called by muse, mutect2, varscan2
- FREM2 | c.3006G>A p.E1002= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV54842868; called by muse, mutect2, varscan2
- GAN | c.1449G>A p.Q483= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV73721063; called by muse, mutect2
- IRF2 | c.732G>A p.E244= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- MCPH1 | c.2449T>C p.L817= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100766246; called by muse, mutect2
- MLLT3 | c.1665C>T p.V555= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV63499030; called by muse, mutect2
- PAQR7 | c.601C>T p.L201= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV65351935; called by muse, mutect2
- SHANK2 | c.4092C>G p.A1364= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV53606533; called by muse, mutect2
- ZNF572 | c.1431C>T p.F477= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV60002191; called by muse, mutect2, varscan2
- SSPOP | n.7687C>A | RNA (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100946928, COSV65132692; called by muse, mutect2
